Somatic mutation profile of tumor specimen TCGA-CG-4477-01A (aliquot TCGA-CG-4477-01A-01D-1158-08) from TCGA case TCGA-CG-4477, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.7 years (21,427 days).
Specimen TCGA-CG-4477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39e45c36-363d-490d-97a8-aced7cf6db1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4477-10A (Blood Derived Normal), aliquot TCGA-CG-4477-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b36b2ea1-2300-4200-b849-fe1c9f8f1f00

The open-access MAF lists 141 somatic variants for this specimen: 117 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 35, Missense Mutation 30, Frame Shift Del 26, Silent 16, In Frame Del 9, In Frame Ins 9, Splice Site 5, Nonsense Mutation 3, Intron 3, RNA 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4319G>A p.W1440* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV70046856; called by muse, mutect2, varscan2
- ACVR1B | c.913del p.I305Lfs*32 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as COSV57778335; called by mutect2, pindel, varscan2
- ADGRD1 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs200971352, COSV55440249; called by muse, mutect2, varscan2
- AKAP13 | c.426C>G p.H142Q | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63471159; called by muse, mutect2, varscan2
- ATP7A | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1557231845, COSV58453335, COSV58455145; called by muse, mutect2
- BPIFB2 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV50063655; called by muse, mutect2, varscan2
- BTBD3 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV54781999; called by muse, mutect2, varscan2
- CCNB3 | c.1105T>A p.F369I | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV52080502; called by muse, mutect2, varscan2
- CDH2 | c.816G>T p.W272C | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52298032; called by muse, mutect2, varscan2
- DMD | c.10997C>G p.S3666C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58952121, COSV58957432; called by muse, mutect2, varscan2
- DUSP12 | c.731_732dup p.A245* | Frame Shift Ins (INS) | VAF 52/340 reads (15%) | catalogued as rs1256113924; called by pindel, varscan2
- EFR3A | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.143); catalogued as COSV54463004; called by muse, mutect2, varscan2
- GABRA3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64806088; called by muse, mutect2, varscan2
- HSPA12A | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65022216, COSV65024108; called by muse, mutect2, varscan2
- KCNA10 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs139383016; called by muse, mutect2, varscan2
- KCNU1 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs764321461, COSV67757463; called by muse, mutect2, varscan2
- KLHL15 | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV60142164; called by muse, mutect2, varscan2
- LMX1B | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as CM992924, COSV100827317; called by muse, varscan2
- LRPPRC | c.3228A>C p.L1076F | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV53243850; called by muse, mutect2, varscan2
- MNDA | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV63741601; called by muse, mutect2, varscan2
- NDRG3 | c.135_136insTG p.I46* (on ENST00000349004 / NM_032013.4; = p.I34* on NM_022477.4) | Frame Shift Ins (INS) | VAF 71/374 reads (19%) | catalogued as COSV100675476; called by mutect2, pindel, varscan2
- OR4C16 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100113823, COSV58944591; called by muse, mutect2, varscan2
- PDIA6 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV55354140; called by muse, mutect2, varscan2
- RASGRP2 | c.71T>C p.F24S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51230661; called by muse, mutect2, varscan2
- RPS6KA6 | c.1854-1G>A p.X618_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV53127593; called by muse, mutect2, varscan2
- SAMHD1 | c.693G>T p.W231C | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53432930; called by muse, mutect2, varscan2
- SH3KBP1 | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1181587402, COSV65650318; called by muse, mutect2, varscan2
- SLC1A5 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946284107, COSV101314839, COSV69467662; called by mutect2, varscan2
- SOGA1 | c.3517A>G p.S1173G | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.64); catalogued as COSV52932675; called by muse, mutect2, varscan2
- SPSB3 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.046); catalogued as COSV51908802; called by muse, mutect2, varscan2
- SREK1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs767997239, COSV52335404; called by muse, mutect2, varscan2
- STOML2 | c.114_116dup p.L39dup | In Frame Ins (INS) | VAF 53/245 reads (22%) | catalogued as COSV100521269; called by mutect2, pindel, varscan2
- SYT6 | c.484C>T p.Q162* (on ENST00000610222 / NM_001366225.1; = p.Q77* on NM_205848.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV65776470; called by muse, mutect2, varscan2
- TMCC3 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151064246, COSV54156331; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, mutect2, varscan2
- TTN | c.82678A>C p.K27560Q (on ENST00000591111; = p.K20136Q on NM_003319.4) | Missense Mutation (SNP) | VAF 67/741 reads (9%) | PolyPhen possibly damaging (0.73); catalogued as COSV60384633; called by muse, mutect2
- WDR88 | c.996_997insCA p.S333Qfs*19 | Frame Shift Ins (INS) | VAF 17/144 reads (12%) | catalogued as COSV100866652; called by mutect2, varscan2
- ZNF484 | c.2459G>C p.S820T | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.05); catalogued as COSV60259815; called by muse, mutect2
- ADAT1 | c.69dup p.K24Efs*3 | Frame Shift Ins (INS) | VAF 26/112 reads (23%) | called by pindel, varscan2
- AGER | c.827_828dup p.P277Cfs*11 | Frame Shift Ins (INS) | VAF 44/193 reads (23%) | called by mutect2, pindel, varscan2
- AHCYL1 | c.1357_1386del p.F453_Q462del | In Frame Del (DEL) | VAF 21/247 reads (9%) | called by mutect2, pindel
- ALMS1 | c.5155_5157dup p.I1719dup | In Frame Ins (INS) | VAF 67/302 reads (22%) | called by mutect2, pindel, varscan2
- ALS2 | c.525_528dup p.G177Yfs*69 | Frame Shift Ins (INS) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- ANKRD40 | c.636del p.V213* | Frame Shift Del (DEL) | VAF 63/324 reads (19%) | called by mutect2, pindel, varscan2
- AR | c.1591dup p.Y531Lfs*21 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- BAZ2A | c.2186_2188dup p.T729dup | In Frame Ins (INS) | VAF 173/816 reads (21%) | called by mutect2, varscan2
- C2CD3 | c.3412dup p.A1138Gfs*9 | Frame Shift Ins (INS) | VAF 35/153 reads (23%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1667_1670dup p.P558Afs*43 | Frame Shift Ins (INS) | VAF 40/256 reads (16%) | called by pindel, varscan2
- C9orf50 | c.1096_1098dup p.S366dup | In Frame Ins (INS) | VAF 24/136 reads (18%) | called by mutect2, varscan2
- CAP1 | c.395_398delinsG p.S132_A133delinsC | In Frame Del (DEL) | VAF 35/170 reads (21%) | called by pindel, varscan2*
- CASD1 | c.2183_2195del p.V728Efs*41 | Frame Shift Del (DEL) | VAF 7/94 reads (7%) | called by mutect2, pindel
- CCDC183 | c.475_478dup p.I160Nfs*31 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- CEBPG | c.366del p.E124Sfs*40 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- CLTC | c.1921del p.V641Ffs*11 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- CPEB4 | c.733_736dup p.H246Pfs*20 | Frame Shift Ins (INS) | VAF 27/206 reads (13%) | called by mutect2, varscan2
- DELE1 | c.174_179del p.G59_G60del | In Frame Del (DEL) | VAF 49/169 reads (29%) | called by mutect2, pindel, varscan2
- ELF3 | c.451dup p.Q151Pfs*10 | Frame Shift Ins (INS) | VAF 43/208 reads (21%) | called by mutect2, pindel, varscan2
- ERI1 | c.917_919dup p.A306dup | In Frame Ins (INS) | VAF 37/233 reads (16%) | called by mutect2, pindel, varscan2
- ESRP1 | c.1971+3_1971+6del p.X657_splice | Splice Site (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- EVL | c.1204del p.I402Sfs*9 (on ENST00000402714 / NM_001330221.2; = p.I404Sfs*9 on NM_016337.3) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel*, varscan2
- EZH1 | c.437_475del p.F146_H159delinsY | In Frame Del (DEL) | VAF 54/357 reads (15%) | called by mutect2, pindel
- F10 | c.414_416delinsA p.F139Lfs*20 | Frame Shift Del (DEL) | VAF 37/189 reads (20%) | called by pindel, varscan2*
- G6PD | c.545_552del p.R182Qfs*9 | Frame Shift Del (DEL) | VAF 30/141 reads (21%) | called by mutect2, pindel, varscan2
- GFM1 | c.304_305del p.I102Sfs*15 | Frame Shift Del (DEL) | VAF 59/274 reads (22%) | called by mutect2, pindel, varscan2
- GJA5 | c.994dup p.R332Pfs*8 | Frame Shift Ins (INS) | VAF 43/212 reads (20%) | called by mutect2, pindel, varscan2
- GLYATL1 | c.196_199del p.D66Tfs*23 (on ENST00000317391 / NM_001354699.1; = p.D97Tfs*23 on NM_080661.4) | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel
- GRN | c.356del p.N119Tfs*137 | Frame Shift Del (DEL) | VAF 61/288 reads (21%) | called by mutect2, pindel, varscan2
- HERC1 | c.7797_7800dup p.V2601Sfs*15 | Frame Shift Ins (INS) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- HKDC1 | c.89_92dup p.S32Afs*4 | Frame Shift Ins (INS) | VAF 35/218 reads (16%) | called by mutect2, pindel, varscan2
- HSPG2 | c.75del p.L26* | Frame Shift Del (DEL) | VAF 79/428 reads (18%) | called by mutect2, pindel, varscan2
- HYLS1 | c.177_185delinsAAGT p.K60Sfs*15 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by pindel, varscan2*
- IGKV2-28 | c.269_280del p.S90_G93del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- IL17REL | c.821_822insGGTT p.F274Lfs*142 | Frame Shift Ins (INS) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- ITGA9 | c.2753_2756dup p.M920Lfs*100 | Frame Shift Ins (INS) | VAF 43/181 reads (24%) | called by mutect2, pindel, varscan2
- KLF4 | c.1358_1360dup p.H453dup | In Frame Ins (INS) | VAF 57/289 reads (20%) | called by mutect2, pindel, varscan2
- KRT33A | c.830_831dup p.T278Afs*24 | Frame Shift Ins (INS) | VAF 64/305 reads (21%) | called by mutect2, pindel, varscan2
- LEMD3 | c.1436del p.T479Mfs*8 | Frame Shift Del (DEL) | VAF 35/179 reads (20%) | called by mutect2, pindel, varscan2
- LRRK2 | c.209_211dup p.S70dup | In Frame Ins (INS) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- LZIC | c.280del p.V94Sfs*17 | Frame Shift Del (DEL) | VAF 71/456 reads (16%) | called by mutect2, pindel, varscan2
- MGA | c.381_384dup p.P129Ifs*5 | Frame Shift Ins (INS) | VAF 105/421 reads (25%) | called by mutect2, pindel, varscan2
- MSANTD2 | c.356_363del p.E119Gfs*73 (on ENST00000374979 / NM_001308027.2; = p.E119Gfs*84 on NM_024631.4) | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- MSH4 | c.1352_1365del p.G451Efs*8 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel
- NAXE | c.228_230dup p.Y76_Q77insH | In Frame Ins (INS) | VAF 66/288 reads (23%) | called by mutect2, pindel, varscan2
- NCDN | c.586dup p.L196Pfs*32 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- NEUROD2 | c.1112_1113del p.P371Hfs*11 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel
- NIN | c.5867_5870dup p.M1958Afs*14 (on ENST00000382041 / NM_182946.1; = p.M1245Afs*14 on NM_016350.4) | Frame Shift Ins (INS) | VAF 10/78 reads (13%) | called by mutect2, pindel
- OGG1 | c.44_48del p.T15Sfs*16 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- OR2S2 | c.454_456del p.I152del | In Frame Del (DEL) | VAF 31/145 reads (21%) | called by mutect2, pindel, varscan2
- PGM2L1 | c.70_71insTACCAC p.P23_Q24insLP | In Frame Ins (INS) | VAF 16/103 reads (16%) | called by mutect2, pindel*
- PHLDB1 | c.3673_3674insCG p.Y1225Sfs*12 | Frame Shift Ins (INS) | VAF 24/197 reads (12%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.2440_2443dup p.R815Tfs*7 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel
- PIK3R3 | c.613del p.T205Hfs*7 | Frame Shift Del (DEL) | VAF 29/233 reads (12%) | called by mutect2, pindel, varscan2
- PLPP1 | c.439_440dup p.I148Tfs*44 | Frame Shift Ins (INS) | VAF 74/403 reads (18%) | called by mutect2, pindel, varscan2
- POLQ | c.4509_4512dup p.P1505Ifs*3 | Frame Shift Ins (INS) | VAF 18/177 reads (10%) | called by mutect2, pindel
- POLR1B | c.2368dup p.S790Kfs*2 | Frame Shift Ins (INS) | VAF 50/237 reads (21%) | called by mutect2, pindel, varscan2
- PRKCI | c.614_620del p.Q205Pfs*10 | Frame Shift Del (DEL) | VAF 41/192 reads (21%) | called by mutect2, pindel, varscan2
- PRPH | c.263_266dup p.F90Gfs*75 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- PRSS8 | c.603_608del p.N202_C203del | In Frame Del (DEL) | VAF 32/130 reads (25%) | called by mutect2, pindel, varscan2
- RBM27 | c.2939_2945dup p.F983Wfs*5 | Frame Shift Ins (INS) | VAF 36/142 reads (25%) | called by mutect2, varscan2
- REEP1 | c.303+1_303+2del p.X101_splice | Splice Site (DEL) | VAF 38/194 reads (20%) | called by mutect2, pindel, varscan2
- RELN | c.10255dup p.A3419Gfs*39 | Frame Shift Ins (INS) | VAF 39/215 reads (18%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.1263+1_1263+12del p.X421_splice | Splice Site (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- SNX27 | c.944_949del p.V315_Y317delinsD | In Frame Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- SPATA2 | c.1529dup p.S511Vfs*32 | Frame Shift Ins (INS) | VAF 52/216 reads (24%) | called by mutect2, pindel, varscan2
- SPECC1 | c.103dup p.S35Ffs*2 | Frame Shift Ins (INS) | VAF 48/290 reads (17%) | called by mutect2, pindel, varscan2
- STX10 | c.314_317dup p.M106Ifs*15 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- TAF1L | c.2166_2170del p.Y722* | Nonsense Mutation (DEL) | VAF 72/294 reads (24%) | called by mutect2, pindel, varscan2
- TBCD | c.3007dup p.Q1003Pfs*5 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel
- TES | c.386_390del p.M129Tfs*28 | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- THBD | c.913_916del p.S305Tfs*76 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- TM4SF1 | c.267+1dup p.X89_splice | Splice Site (INS) | VAF 82/388 reads (21%) | called by mutect2, pindel, varscan2
- TMCO6 | c.401_404dup p.S136Afs*11 | Frame Shift Ins (INS) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- TP53 | c.662_666del p.E221Afs*2 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- TRIM31 | c.494_498delinsCTT p.H165Pfs*12 | Frame Shift Del (DEL) | VAF 61/454 reads (13%) | called by pindel, varscan2*
- UPK3B | c.398_400delinsTT p.N133Ifs*22 (on ENST00000257632; = p.N78Ifs*22 on NM_001347684.2) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2*
- WNK2 | c.3938dup p.I1314Hfs*7 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- ZC3H12A | c.1411_1413del p.Y471del | In Frame Del (DEL) | VAF 37/241 reads (15%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.1626A>G p.A542= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as COSV51859796; called by muse, mutect2, varscan2
- AP3B2 | c.753C>T p.F251= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55615025; called by muse, mutect2, varscan2
- APOB | c.6213C>T p.L2071= | Silent (SNP) | VAF 49/198 reads (25%) | catalogued as COSV51955253; called by muse, mutect2, varscan2
- APOB | c.3051C>T p.S1017= | Silent (SNP) | VAF 55/259 reads (21%) | catalogued as rs558838327, COSV51921739, COSV99267990; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTBD3 | c.528T>A p.A176= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as COSV54782009; called by muse, mutect2, varscan2
- COX15 | c.738C>T p.L246= | Silent (SNP) | VAF 51/218 reads (23%) | catalogued as rs572833889, COSV50013414; called by muse, mutect2, varscan2
- IRF3 | c.1182C>T p.H394= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs950940915, COSV59192872; called by muse, mutect2, varscan2
- MAST1 | c.1305C>T p.V435= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1458672387, COSV52256130; called by muse, mutect2
- OR2T33 | c.579C>T p.F193= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs1439477620, COSV58815866; called by muse, mutect2, varscan2
- RAB6B | c.513G>T p.A171= | Silent (SNP) | VAF 41/209 reads (20%) | catalogued as COSV53316019; called by muse, mutect2, varscan2
- SH3BP4 | c.2286C>A p.L762= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV60646832; called by muse, mutect2, varscan2
- SLC25A20 | c.603A>T p.G201= | Silent (SNP) | VAF 13/248 reads (5%) | catalogued as COSV59804905; called by muse, mutect2
- SLC45A4 | c.1008C>T p.H336= (on ENST00000517878 / NM_001286646.2; = p.H285= on NM_001080431.2) | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as rs774118130, COSV50150759; called by muse, mutect2, varscan2
- SPAG6 | c.378A>C p.A126= | Silent (SNP) | VAF 41/190 reads (22%) | catalogued as COSV57624567; called by muse, mutect2, varscan2
- TRPC7 | c.324C>T p.D108= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as rs752389161, COSV61462018; called by muse, mutect2, varscan2
- ZNF554 | c.1584G>A p.A528= | Silent (SNP) | VAF 62/226 reads (27%) | catalogued as rs545329205, COSV57885680, COSV57885788; called by muse, mutect2
- AL353804.4 | chrX:73823998 G>C | 5'Flank (SNP) | VAF 3/31 reads (10%) | catalogued as rs1307702761; called by muse, mutect2
- BRSK2 | c.1227-1913_1227-1910dup | Intron (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- CELF2 | c.53+12688_53+12693del | Intron (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel*
- CPLANE1 | c.*5222C>T | 3'UTR (SNP) | VAF 36/277 reads (13%) | catalogued as rs1348795271, COSV57075933; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117801 del C | 3'Flank (DEL) | VAF 58/200 reads (29%) | catalogued as COSV50993728; called by mutect2, pindel, varscan2
- FGF8 | c.157-31_157-28dup | Intron (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- FOLH1B | n.973G>A | RNA (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- MIR1251 | n.39_43del | RNA (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
